Somatic mutation profile of tumor specimen TCGA-VQ-AA68-01A (aliquot TCGA-VQ-AA68-01A-11D-A410-08) from TCGA case TCGA-VQ-AA68, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 52.9 years (19,304 days).
Specimen TCGA-VQ-AA68-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04103b6d-d9a1-4428-a5cb-bfacba073226.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA68-10A (Blood Derived Normal), aliquot TCGA-VQ-AA68-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a3d5ea1-61a0-479b-a2b7-3ac57f118108

The open-access MAF lists 181 somatic variants for this specimen: 145 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 33, Nonsense Mutation 7, Frame Shift Del 5, Intron 2, Frame Shift Ins 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1202682161, CM043821, COSV99377310; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.2393T>A p.L798H | Missense Mutation (SNP) | VAF 47/85 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725903, COSV61483358, COSV61493836; called by muse, mutect2, varscan2
- ABCA13 | c.14362G>A p.V4788M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.294); catalogued as rs373171750; called by muse, mutect2, varscan2
- ACSM2A | c.1710G>T p.M570I (on ENST00000219054; = p.M491I on NM_001308169.2) | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs757378811, COSV54584726, COSV99525284; called by muse, mutect2, varscan2
- AFF2 | c.1925A>G p.E642G | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.451); catalogued as COSV99664179; called by muse, mutect2, varscan2
- AHNAK2 | c.13406A>G p.K4469R | Missense Mutation (SNP) | VAF 344/474 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100317623; called by muse, mutect2, varscan2
- ALG1 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV99275773; called by muse, mutect2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | catalogued as rs774148781; called by mutect2, varscan2
- ARID1B | c.3238G>C p.V1080L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51650679, COSV51682107; called by muse, mutect2, varscan2
- B3GLCT | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV58455624; called by muse, mutect2, varscan2
- BEND4 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs759939750, COSV101549753; called by muse, varscan2
- BRAF | c.1770G>A p.M590I (on ENST00000288602 / NM_001374244.1; = p.M550I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV99961805; called by muse, mutect2, varscan2
- C10orf90 | c.1731A>C p.E577D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52953509; called by muse, mutect2, varscan2
- CBLN1 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99535677; called by muse, mutect2, varscan2
- CCNB1 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs769965059, COSV99841303; called by muse, mutect2, varscan2
- CD1C | c.664T>A p.L222M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.705); catalogued as COSV100939392; called by muse, mutect2, varscan2
- CDH2 | c.2405A>C p.K802T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99296991; called by muse, mutect2, varscan2
- CDH8 | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180616; called by muse, mutect2, varscan2
- CFH | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.753); catalogued as rs1332043837, COSV100809094; called by muse, mutect2, varscan2
- CSMD1 | c.949T>G p.L317V | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV101227511, COSV68173437; called by muse, mutect2, varscan2
- CSMD3 | c.6940A>G p.R2314G (on ENST00000297405 / NM_001363185.1; = p.R2210G on NM_052900.3) | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs750004286, COSV52160571, COSV99846677; called by muse, mutect2, varscan2
- CT45A3 | c.533T>G p.V178G | Missense Mutation (SNP) | VAF 42/1221 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs1259257667; called by muse, mutect2
- CUZD1 | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100158830; called by muse, mutect2, varscan2
- CYP4F2 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as rs866736048, COSV99686035; called by muse, mutect2, varscan2
- DAB1 | c.1668A>C p.E556D (on ENST00000371231; = p.E523D on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64691122; called by muse, mutect2, varscan2
- EHMT2 | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs760598456, COSV64996224; called by muse, mutect2, varscan2
- EPHB1 | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101213206, COSV67675147; called by muse, varscan2
- EPX | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781542790, COSV56596373, COSV56598396; called by muse, mutect2, varscan2
- EPYC | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs758493947, COSV53802093; called by muse, mutect2, varscan2
- EXOC6B | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1399262432, COSV99724430; called by muse, mutect2, varscan2
- F2RL2 | c.994A>C p.N332H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV99167340; called by muse, mutect2, varscan2
- FAT1 | c.5315G>T p.G1772V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499370; called by muse, mutect2, varscan2
- FCER1A | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100929271; called by muse, mutect2, varscan2
- FCRL3 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV100943260; called by muse, mutect2, varscan2
- FGFRL1 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs754703776, COSV53257325, COSV99294664; called by muse, mutect2, varscan2
- FLG2 | c.2821A>G p.S941G | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV101165894, COSV66168956; called by muse, mutect2, varscan2
- FMN2 | c.4788A>C p.K1596N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100145204; called by muse, mutect2, varscan2
- FMNL2 | c.2396C>T p.T799I | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV99979761; called by muse, mutect2, varscan2
- GP5 | c.1663A>G p.R555G | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100540888; called by muse, mutect2, varscan2
- HECW2 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs1315571850, COSV99647295; called by muse, mutect2, varscan2
- HK2 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 213/468 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99309082; called by muse, mutect2, varscan2
- IRX1 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100116504; called by muse, mutect2, varscan2
- ITPR1 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100231389, COSV56991018, COSV56992762; called by muse, mutect2
- KIAA1210 | c.1675C>A p.Q559K | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV101274170; called by muse, mutect2, varscan2
- KIF24 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs547247232, COSV61458077; called by muse, mutect2, varscan2
- KLHL40 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187688307, COSV99825551; called by muse, mutect2, varscan2
- LAMA1 | c.5951T>A p.V1984D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs750771141, COSV101056509; called by muse, mutect2, varscan2
- LAMA1 | c.5699C>A p.T1900N | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV101056511; called by muse, mutect2, varscan2
- LRFN5 | c.1025T>G p.L342R | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53245388, COSV53273192; called by muse, mutect2, varscan2
- LRRIQ1 | c.1614A>T p.E538D | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV101280434; called by muse, mutect2, varscan2
- LRRTM4 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV69140615; called by muse, varscan2
- LTBP2 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs1210629720, COSV100000374; called by muse, mutect2, varscan2
- MAP9 | c.177T>G p.F59L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.352); catalogued as COSV100250911; called by muse, mutect2, varscan2
- MEOX1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs147458484, COSV100233700; called by muse, mutect2, varscan2
- MRO | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.839); catalogued as COSV56498760; called by muse, mutect2, varscan2
- MTX1 | c.616C>G p.R206G | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV100003385; called by muse, mutect2, varscan2
- MYCBP2 | c.5081G>A p.S1694N (on ENST00000357337; = p.S1732N on NM_015057.5) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.895); catalogued as COSV100630452; called by muse, mutect2, varscan2
- NAV3 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV99891385; called by muse, mutect2, varscan2
- NBEAL2 | c.6578G>A p.R2193Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1485959887, COSV99436010; called by muse, mutect2, varscan2
- NES | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 70/166 reads (42%) | catalogued as COSV100957873; called by muse, mutect2, varscan2
- NLGN4X | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs398124363, COSV52024869; called by muse, mutect2, varscan2
- NSFL1C | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99401407; called by muse, mutect2, varscan2
- NTSR2 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs201528903, COSV100183914; called by muse, mutect2, varscan2
- NUDT11 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV101047060; called by muse, mutect2, varscan2
- NUP98 | c.5267G>A p.R1756H (on ENST00000359171 / NM_001365126.1; = p.R1739H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763063541, COSV51708728; called by muse, mutect2, varscan2
- OBSCN | c.9832G>A p.G3278R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as rs750419068, COSV99478651; called by muse, mutect2, varscan2
- OBSCN | c.11314C>T p.R3772C | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs1043271907, COSV52769545; called by muse, mutect2, varscan2
- OPCML | c.1028T>G p.I343S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV100101632; called by muse, mutect2, varscan2
- OR10G7 | c.314T>A p.F105Y | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100389945; called by muse, mutect2, varscan2
- OR10X1 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.043); catalogued as COSV100936665; called by muse, mutect2, varscan2
- OR2J3 | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV101013635; called by muse, mutect2, varscan2
- OR2L3 | c.701A>G p.K234R | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.35); catalogued as rs1319206708, COSV100741976, COSV63456466; called by muse, mutect2, varscan2
- OR4A5 | c.100T>A p.L34M | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as COSV100157107, COSV60523528; called by muse, mutect2, varscan2
- OR4C6 | c.313T>G p.F105V | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); catalogued as COSV100051648; called by muse, mutect2, varscan2
- OR5A2 | c.716T>C p.F239S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100119749; called by muse, mutect2, varscan2
- OR5D16 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV101003959; called by muse, mutect2, varscan2
- OR5M3 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100392520, COSV56565606; called by muse, mutect2, varscan2
- OR5T3 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57380409; called by muse, mutect2, varscan2
- OR8D2 | c.644T>G p.L215R | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100659003; called by muse, mutect2, varscan2
- PABPC3 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200575875; called by muse, mutect2, varscan2
- PAX1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769029399, COSV101270311; called by muse, mutect2, varscan2
- PCDHA12 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56479342; called by muse, mutect2, varscan2
- PCDHGA6 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1169979924, COSV99528851, COSV99535132; called by muse, mutect2, varscan2
- PCLO | c.13607A>G p.K4536R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV61639634; called by muse, mutect2, varscan2
- PCSK2 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287184967, COSV52737337; called by muse, mutect2, varscan2
- PLEKHM1 | c.2093G>A p.W698* | Nonsense Mutation (SNP) | VAF 34/109 reads (31%) | catalogued as COSV101378750; called by muse, mutect2, varscan2
- PPP1R16B | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100239505; called by muse, varscan2
- PREX2 | c.1963T>G p.F655V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99907446; called by muse, mutect2, varscan2
- PTH2R | c.1640A>G p.E547G | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99782500; called by muse, mutect2
- PTK2B | c.2215G>A p.V739I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs760981859, COSV100593913; called by muse, mutect2, varscan2
- RAB6B | c.17A>C p.D6A | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99558030; called by muse, mutect2, varscan2
- RIMKLB | c.508T>G p.L170V | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV55237004; called by muse, mutect2, varscan2
- RIPK1 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs575530112, COSV99454464; called by muse, mutect2, varscan2
- RNF38 | c.416G>C p.S139T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99425094; called by muse, mutect2, varscan2
- ROMO1 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99488596; called by muse, mutect2, varscan2
- RPS6KB2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); catalogued as rs780978333, COSV100412252, COSV100412404; called by muse, mutect2, varscan2
- RSC1A1 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100197637; called by muse, mutect2
- RTL3 | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as COSV100329816; called by muse, mutect2, varscan2
- SACS | c.6215T>G p.L2072R | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.64); catalogued as COSV101207467; called by muse, mutect2, varscan2
- SCN10A | c.1589A>C p.H530P | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV101479404; called by muse, mutect2, varscan2
- SLC18A3 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV60319635; called by muse, mutect2, varscan2
- SLC39A4 | c.1820C>T p.P607L (on ENST00000301305 / NM_001374839.1; = p.P582L on NM_017767.3) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782571751, COSV99433387; called by muse, mutect2, varscan2
- SLCO1C1 | c.1291T>A p.S431T | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV99859170; called by muse, mutect2, varscan2
- SLITRK3 | c.421A>G p.R141G | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99579308; called by muse, mutect2, varscan2
- SLITRK5 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs745820982, COSV100280788, COSV61526783; called by muse, mutect2, varscan2
- SMG5 | c.1501C>T p.L501F | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV100700791; called by muse, mutect2, varscan2
- SMYD1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV101352449; called by muse, mutect2, varscan2
- SNRNP200 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs1477327778, COSV60496218; called by muse, mutect2, varscan2
- SPTA1 | c.5413A>G p.K1805E | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.313); catalogued as rs770623394, COSV100935015; called by muse, mutect2, varscan2
- SPTA1 | c.3314A>C p.N1105T | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.855); catalogued as rs200193956, COSV63760928; called by muse, mutect2, varscan2
- SPTA1 | c.2809C>T p.L937F | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100935017; called by muse, mutect2
- SPTA1 | c.967T>G p.L323V | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV100935018; called by muse, mutect2, varscan2
- SPTBN5 | c.9965G>A p.R3322H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs377459229; called by muse, mutect2, varscan2
- STOX1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs552663223, COSV53815843; called by muse, mutect2
- SYT10 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99951439; called by muse, mutect2
- TASOR | c.4189A>G p.T1397A (on ENST00000355628 / NM_001365636.2; = p.T1021A on NM_015224.3) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs767499232, COSV100413998; called by muse, mutect2, varscan2
- TECTA | c.1255A>C p.K419Q | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.863); catalogued as COSV99879958; called by muse, mutect2, varscan2
- TECTA | c.5635G>A p.A1879T | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as rs766297094, COSV50696560; called by muse, mutect2, varscan2
- TESK2 | c.1635A>C p.E545D | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); catalogued as COSV100517386; called by muse, mutect2, varscan2
- TEX15 | c.6437A>G p.N2146S (on ENST00000256246; = p.N2529S on NM_001350162.2) | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV99821399; called by muse, mutect2, varscan2
- TLX2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1396702246, COSV99283646; called by muse, mutect2, varscan2
- TP53 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV52760587, COSV52765100, COSV53340164, COSV53452066; called by muse, varscan2
- TRAM1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as rs199715423, COSV99140783; called by muse, mutect2, varscan2
- TRIM63 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as rs1426417166, COSV100958156; called by muse, mutect2, varscan2
- TRPA1 | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100084230; called by muse, mutect2, varscan2
- TRPM6 | c.3746T>G p.L1249R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100666390; called by muse, mutect2, varscan2
- TTN | c.61250G>T p.R20417L (on ENST00000591111; = p.R12993L on NM_003319.4) | Missense Mutation (SNP) | VAF 43/85 reads (51%) | PolyPhen benign (0.247); catalogued as rs753077711, COSV60113637; called by muse, mutect2, varscan2
- TTN | c.27529A>C p.S9177R (on ENST00000591111; = p.S8250R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/81 reads (56%) | PolyPhen benign (0.219); catalogued as COSV100614562; called by muse, mutect2, varscan2
- UBR5 | c.5818G>A p.D1940N | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99640950; called by muse, mutect2, varscan2
- USP13 | c.2269C>G p.L757V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.923); catalogued as COSV99831191; called by muse, mutect2, varscan2
- VIP | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100923939; called by muse, mutect2, varscan2
- ZBTB8OS | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100542284; called by muse, mutect2
- ZNF205 | c.413G>A p.W138* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV99530427; called by muse, mutect2, varscan2
- ZNF521 | c.1441T>G p.F481V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV64125830, COSV64130310; called by muse, mutect2, varscan2
- ZP4 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs878994307, COSV100850689; called by muse, mutect2, varscan2
- ABHD13 | c.664dup p.I222Nfs*25 | Frame Shift Ins (INS) | VAF 26/143 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD6 | c.1382del p.L461Wfs*4 | Frame Shift Del (DEL) | VAF 19/39 reads (49%) | called by mutect2, pindel, varscan2
- MUC16 | c.28del p.S10Hfs*8 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PHC3 | c.1129_1130del p.H378Sfs*9 (on ENST00000494943 / NM_001308116.2; = p.H390Sfs*9 on NM_024947.4) | Frame Shift Del (DEL) | VAF 54/197 reads (27%) | called by pindel, varscan2
- PKHD1 | c.5984_5985del p.E1995Afs*57 | Frame Shift Del (DEL) | VAF 51/207 reads (25%) | called by pindel, varscan2
- RBP3 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC22A20P | n.1405G>T | Splice Region (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- SPATA31A3 | c.2212T>G p.L738V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.219); called by mutect2, varscan2
- SPTA1 | c.7183del p.Y2395Ifs*37 | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | called by mutect2, pindel*, varscan2
- TPTE | c.545A>C p.K182T (on ENST00000618007 / NM_199261.4; = p.K164T on NM_199259.4) | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ABCB1 | c.1800T>G p.G600= | Silent (SNP) | VAF 44/75 reads (59%) | catalogued as COSV99713123; called by muse, mutect2, varscan2
- ADGRB3 | c.1096A>C p.R366= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV101002045, COSV65397061, COSV65406871; called by muse, mutect2, varscan2
- ADGRG7 | c.1506C>T p.D502= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as COSV99841077; called by muse, mutect2, varscan2
- APOB | c.2400G>C p.L800= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV51948470, COSV99265782; called by muse, mutect2, varscan2
- ARHGAP20 | c.3336T>C p.S1112= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV99503186; called by muse, mutect2, varscan2
- BNC2 | c.2787C>T p.L929= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs774762974, COSV66161355; called by muse, mutect2, varscan2
- C6orf118 | c.270C>T p.R90= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as rs200236975, COSV57814583, COSV57816797; called by muse, mutect2, varscan2
- CACNA1E | c.3513G>A p.A1171= | Silent (SNP) | VAF 63/181 reads (35%) | catalogued as rs565145928, COSV62433924; called by muse, mutect2, varscan2
- CFD | c.378G>A p.L126= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1438325875, COSV100576646; called by muse, mutect2, varscan2
- COL4A5 | c.4594A>C p.R1532= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs748695668, COSV100087868, COSV60367471; called by muse, mutect2, varscan2
- CZIB | c.372G>A p.G124= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV99598154; called by muse, mutect2, varscan2
- DCDC1 | c.4398T>C p.R1466= (on ENST00000597505 / NM_001367979.1; = p.R573= on NM_020869.3) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs763809059, COSV100338306; called by muse, varscan2
- FOXRED2 | c.1431G>C p.L477= | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as COSV99340921; called by muse, mutect2, varscan2
- H1-0 | c.519C>T p.P173= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs912881383, COSV99959806; called by muse, mutect2, varscan2
- H2AC1 | c.216C>T p.R72= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs763406620, COSV51237643; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1245T>C p.T415= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV100780640, COSV100781340; called by muse, mutect2, varscan2
- LRIG1 | c.3186C>T p.L1062= | Silent (SNP) | VAF 14/159 reads (9%) | catalogued as rs767537467, COSV99833805; called by muse, mutect2
- NAB1 | c.936T>C p.Y312= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100493018; called by muse, mutect2, varscan2
- NXPH1 | c.157T>C p.L53= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as COSV101339701, COSV68318636; called by muse, mutect2, varscan2
- OR4C13 | c.682T>C p.L228= | Silent (SNP) | VAF 68/123 reads (55%) | catalogued as COSV101634183; called by muse, mutect2, varscan2
- PLEC | c.3192C>T p.H1064= (on ENST00000322810 / NM_201380.4; = p.H954= on NM_000445.5) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1554712019, COSV100514483; called by muse, mutect2, varscan2
- PNLIP | c.816T>C p.T272= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV100981639, COSV100981813; called by muse, mutect2, varscan2
- POU4F2 | c.939C>T p.I313= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99850564; called by muse, mutect2
- PTCHD3 | c.702C>T p.G234= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs1320937431, COSV71256462; called by muse, mutect2, varscan2
- RADIL | c.2511C>T p.H837= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs778980429, COSV101271432; called by muse, varscan2
- RTL3 | c.453A>G p.Q151= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs1329636864, COSV58186153; called by muse, mutect2, varscan2
- SERPINI1 | c.1149G>A p.R383= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV99855094; called by muse, mutect2, varscan2
- SNX20 | c.303C>T p.I101= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100319063; called by muse, mutect2, varscan2
- SYNE1 | c.7620G>A p.T2540= (on ENST00000367255 / NM_182961.4; = p.T2547= on NM_033071.3) | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs142663488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TELO2 | c.1767C>T p.A589= | Silent (SNP) | VAF 56/102 reads (55%) | catalogued as rs1224795157, COSV99248377; called by muse, mutect2, varscan2
- UMOD | c.1801T>C p.L601= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100208388; called by muse, mutect2, varscan2
- VIP | c.96T>G p.P32= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100923938; called by muse, mutect2, varscan2
- ZNF713 | c.96G>A p.E32= (on ENST00000633730 / NM_001366796.2; = p.E45= on NM_182633.3) | Silent (SNP) | VAF 73/152 reads (48%) | catalogued as COSV101289510; called by muse, mutect2, varscan2
- NRG1 | c.502+30961T>G | Intron (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99828471; called by muse, mutect2, varscan2
- TMEM91 | c.361-140G>T | Intron (SNP) | VAF 26/46 reads (57%) | catalogued as COSV99652670; called by muse, varscan2
- ZNF658B | n.837T>A | RNA (SNP) | VAF 69/258 reads (27%) | called by muse, mutect2, varscan2
